Somatic mutation profile of tumor specimen C3N-00574-01 (aliquot CPT0090860013) from CPTAC case C3N-00574, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 40.7 years (14,867 days).
Specimen C3N-00574-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89666833-08bd-4d75-b8c1-6fb9641301df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00574-31 (Blood Derived Normal), aliquot CPT0090980002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59a5d50b-c900-43c5-ac7c-cccd0f2bf03c

The open-access MAF lists 70 somatic variants for this specimen: 44 protein-altering or splice-affecting, 20 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 20, 5'UTR 3, Intron 3, Nonsense Mutation 3, In Frame Del 2, Splice Site 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 3043/3530 reads (86%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- CALCRL | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs761424831, COSV66474118; called by muse, varscan2
- CAPN6 | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV99047909; called by muse, mutect2, varscan2
- CPT1C | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1243005888, COSV54921130, COSV54922438; called by muse, mutect2
- CSRNP3 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as rs766623860, COSV58775184; called by muse, mutect2, varscan2
- DDX52 | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1352345144; called by muse, mutect2
- EDA2R | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs755280381, COSV53631159; called by muse, mutect2, varscan2
- ERMN | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs554539666, COSV68075808; called by muse, mutect2
- FAM184B | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.487); catalogued as rs899848754, COSV53954518; called by muse, mutect2, varscan2
- FSIP2 | c.10210C>T p.R3404W | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs546038705; called by muse, varscan2
- HUWE1 | c.5975G>A p.R1992Q | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.455); catalogued as rs199846544, COSV53364192; called by muse, mutect2, varscan2
- ITPR3 | c.7159G>A p.G2387S | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477631898; called by muse, mutect2, varscan2
- KCNK17 | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV100950249; called by muse, mutect2, varscan2
- LAMB4 | c.4184C>T p.T1395M | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs187471926, COSV99063876; called by muse, mutect2, varscan2
- NLRP9 | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV100243577; called by muse, mutect2
- PATJ | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.764); catalogued as rs545651035, COSV57155825; called by muse, mutect2
- PCDH9 | c.3141G>A p.S1047= (on ENST00000377865 / NM_203487.3; = p.S1013= on NM_020403.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 10/91 reads (11%) | catalogued as rs776019485, COSV60594482; called by muse, mutect2, varscan2
- PELI1 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62729680; called by muse, mutect2, varscan2
- PLPBP | c.158T>C p.M53T | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs1334303637; called by muse, mutect2, varscan2
- PRSS1 | c.136C>A p.H46N | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV61198466; called by muse, mutect2
- RYR2 | c.10261G>T p.V3421L | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV100770776; called by muse, mutect2, varscan2
- SLC12A1 | c.3240C>A p.N1080K | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs1239885878; called by muse, mutect2
- SPTA1 | c.5432+1G>T p.X1811_splice | Splice Site (SNP) | VAF 21/562 reads (4%) | catalogued as COSV63749838, COSV63758259; called by muse, mutect2
- TP53 | c.709_713del p.M237* | Frame Shift Del (DEL) | VAF 166/364 reads (46%) | catalogued as COSV52937694; called by mutect2, pindel, varscan2
- BCOR | c.3967A>T p.K1323* (on ENST00000378444 / NM_001123385.2; = p.K1289* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- CHD2 | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 80/404 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CSMD2 | c.6226T>A p.L2076M | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.147); called by muse, mutect2
- DSC3 | c.235_239dup p.Y80* | Nonsense Mutation (INS) | VAF 14/174 reads (8%) | called by mutect2, pindel
- FLG | c.3313G>A p.D1105N | Missense Mutation (SNP) | VAF 57/562 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2
- MACF1 | c.11294C>T p.S3765F (on ENST00000372915; = p.S1698F on NM_012090.5) | Missense Mutation (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- MED4 | c.776C>G p.S259* | Nonsense Mutation (SNP) | VAF 36/109 reads (33%) | called by muse, mutect2, varscan2
- MUC5B | c.14435C>G p.T4812S | Missense Mutation (SNP) | VAF 97/470 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAALADL2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2M2 | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 44/379 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- OR2T4 | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 58/438 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDH8 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIP4K2A | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- POU6F2 | c.1186A>G p.I396V | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- RASGRF2 | c.2777T>C p.V926A | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RRAGB | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SIAE | c.100A>G p.N34D | Missense Mutation (SNP) | VAF 134/490 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC5A6 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 104/309 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SPRY2 | c.471_473del p.E157_L158delinsD | In Frame Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- SRGAP2 | c.2066A>G p.Y689C (on ENST00000624873 / NM_001170637.4; = p.Y690C on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ACP4 | c.417C>T p.I139= | Silent (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- ADGRL3 | c.4518C>G p.T1506= (on ENST00000506720 / NM_001322402.2; = p.T1395= on NM_015236.6) | Silent (SNP) | VAF 24/210 reads (11%) | called by muse, mutect2, varscan2
- APOA4 | c.612C>T p.Y204= | Silent (SNP) | VAF 54/544 reads (10%) | catalogued as rs201385362, COSV63361128; called by muse, mutect2
- BAP1 | c.775C>T p.L259= | Silent (SNP) | VAF 118/380 reads (31%) | called by muse, mutect2, varscan2
- CCDC105 | c.1149G>A p.S383= | Silent (SNP) | VAF 25/148 reads (17%) | catalogued as rs765555278, COSV52963819, COSV99479932; called by muse, mutect2, varscan2
- CDC42BPG | c.3723C>T p.G1241= | Silent (SNP) | VAF 50/339 reads (15%) | catalogued as rs780862462; called by muse, mutect2, varscan2
- FLNC | c.651C>T p.N217= | Silent (SNP) | VAF 23/224 reads (10%) | catalogued as rs370425863; called by muse, mutect2
- GABBR2 | c.2226G>A p.P742= | Silent (SNP) | VAF 17/195 reads (9%) | catalogued as rs79435794; called by muse, mutect2
- H1-7 | c.297G>T p.A99= | Silent (SNP) | VAF 43/349 reads (12%) | catalogued as COSV58602604; called by muse, mutect2, varscan2
- HAL | c.1266G>A p.L422= | Silent (SNP) | VAF 12/268 reads (4%) | catalogued as COSV54117509; called by muse, mutect2
- KRT2 | c.852G>C p.T284= | Silent (SNP) | VAF 149/411 reads (36%) | catalogued as COSV59009938, COSV59013187; called by muse, mutect2, varscan2
- LRIG3 | c.2184G>A p.L728= | Silent (SNP) | VAF 1039/2313 reads (45%) | called by muse, mutect2, varscan2
- LRP1 | c.7758C>T p.N2586= | Silent (SNP) | VAF 134/365 reads (37%) | catalogued as rs377443144; called by muse, mutect2, varscan2
- MNT | c.1542C>T p.P514= | Silent (SNP) | VAF 25/222 reads (11%) | catalogued as rs1315789284, COSV51512828; called by muse, mutect2, varscan2
- NRDE2 | c.3402C>T p.P1134= | Silent (SNP) | VAF 69/247 reads (28%) | catalogued as rs750217500, COSV100583319; called by muse, mutect2, varscan2
- PLXNA1 | c.5016C>T p.S1672= | Silent (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- SLC2A9 | c.825G>A p.T275= | Silent (SNP) | VAF 28/253 reads (11%) | catalogued as rs375484164; called by muse, mutect2, varscan2
- SLC6A12 | c.1053C>A p.P351= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- SNTA1 | c.360A>T p.G120= | Silent (SNP) | VAF 94/876 reads (11%) | called by muse, mutect2, varscan2
- TGIF2LX | c.600G>A p.P200= | Silent (SNP) | VAF 17/279 reads (6%) | catalogued as COSV52213488; called by muse, mutect2
- CDH4 | c.170-24749C>T | Intron (SNP) | VAF 12/214 reads (6%) | catalogued as rs1374006928; called by muse, mutect2
- FAM71D | c.160-1605G>A | Intron (SNP) | VAF 64/272 reads (24%) | called by muse, varscan2
- HTRA4 | c.-26A>T | 5'UTR (SNP) | VAF 42/273 reads (15%) | called by muse, mutect2, varscan2
- IQCF1 | c.-36G>A | 5'UTR (SNP) | VAF 24/211 reads (11%) | called by muse, mutect2, varscan2
- TNFAIP8 | c.-3C>G | 5'UTR (SNP) | VAF 42/150 reads (28%) | catalogued as COSV57225444, COSV57227443; called by muse, mutect2, varscan2
- TRIM61 | c.526-2190_526-2189del | Intron (DEL) | VAF 38/438 reads (9%) | called by mutect2, pindel
